Somatic mutation profile of tumor specimen 0DMN25 from CCDI case PBCARV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Desmoplastic small round cell tumor; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 14.9 years (5,460 days).
Specimen 0DMN25: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95044e69-1735-4da6-9a58-726a9acfa361.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMN1C (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/daacdbcc-df1f-4bc8-b318-34c9eb1ac9ad

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 3, Nonsense Mutation 2, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH20 | c.1570C>T p.R524C | Missense Mutation (SNP) | VAF 83/193 reads (43%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.601); catalogued as rs185626136; called by muse, varscan2
- CPO | c.572G>A p.C191Y | Missense Mutation (SNP) | VAF 50/180 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.58); catalogued as rs759901800; called by muse, varscan2
- HMCN2 | c.8696G>A p.R2899Q | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as rs1205245295; called by muse, varscan2
- KIF21B | c.1264C>T p.R422* | Nonsense Mutation (SNP) | VAF 24/120 reads (20%) | catalogued as rs140412174; called by muse, varscan2
- OR51E2 | c.12C>A p.C4* | Nonsense Mutation (SNP) | VAF 38/219 reads (17%) | called by muse, varscan2
- PPP1R36 | c.883del p.Q295Sfs*5 | Frame Shift Del (DEL) | VAF 8/85 reads (9%) | called by pindel, varscan2
- PPP1R42 | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 56/205 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- RELL2 | c.536G>C p.G179A | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, varscan2
- CRACD | c.651C>T p.S217= | Silent (SNP) | VAF 39/162 reads (24%) | catalogued as COSV51721559, COSV51735396, COSV99950170; called by muse, varscan2
- PCDHA6 | c.390G>A p.P130= | Silent (SNP) | VAF 24/132 reads (18%) | catalogued as rs370641869; called by muse, varscan2
- PPOX | c.391C>T p.L131= | Silent (SNP) | VAF 14/118 reads (12%) | called by muse, varscan2
- PPP6R1 | c.552+33del | Intron (DEL) | VAF 4/33 reads (12%) | called by pindel, varscan2
